Somatic mutation profile of tumor specimen TCGA-AP-A0LJ-01A (aliquot TCGA-AP-A0LJ-01A-11W-A062-09) from TCGA case TCGA-AP-A0LJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 42.6 years (15,577 days).
Specimen TCGA-AP-A0LJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a532b515-9fef-4ea8-ac60-5e43c7c69ecf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LJ-10A (Blood Derived Normal), aliquot TCGA-AP-A0LJ-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1fb89c8-2d09-489e-a42b-e4137beee41a

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 29, Silent 10, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 19/59 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SOS1 | c.697A>T p.N233Y | Missense Mutation (SNP) | VAF 20/73 reads (27%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as rs1057519963, COSV67673722; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AICDA | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV57563821; called by muse, mutect2, varscan2
- ARHGEF4 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs777163056, COSV58119803, COSV58127430; called by muse, mutect2, varscan2
- B3GNT3 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs1340665314, COSV57952972; called by muse, mutect2, varscan2
- CD5L | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145458344, COSV63821515; called by muse, mutect2, varscan2
- CLDN16 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs549642537, COSV53227390; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNGB1 | c.3285C>A p.S1095R | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.634); catalogued as COSV51899200; called by muse, mutect2, varscan2
- CYBB | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 41/408 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66085105, COSV66086422; called by muse, mutect2, varscan2
- DECR2 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.849); catalogued as rs199827797, COSV54791185; called by muse, mutect2, varscan2
- DNAH9 | c.9856C>T p.R3286C | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs990212558, COSV52342960; called by muse, mutect2, varscan2
- DRC7 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1211640046, COSV61053909; called by muse, mutect2
- E2F1 | c.392C>G p.S131* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV58534737, COSV58536072; called by muse, mutect2
- FRMPD3 | c.3778C>T p.R1260C | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs754874618, COSV52188549; called by muse, mutect2, varscan2
- GAREM1 | c.2357C>T p.P786L (on ENST00000269209 / NM_001242409.2; = p.P785L on NM_022751.3) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs766426013, COSV52507558; called by muse, mutect2, varscan2
- IFT43 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 82/324 reads (25%) | catalogued as rs572289925, COSV53137809; called by muse, mutect2, varscan2
- LRRK1 | c.2359G>A p.G787S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs367783860; called by muse, mutect2, varscan2
- LZTS2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs773834150, COSV64651301; called by muse, mutect2, varscan2
- MACF1 | c.6902G>C p.G2301A | Missense Mutation (SNP) | VAF 41/179 reads (23%) | catalogued as COSV57114307; called by muse, mutect2, varscan2
- NHS | c.3932G>C p.R1311T | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV66273222; called by muse, mutect2
- OR51Q1 | c.509T>C p.F170S | Missense Mutation (SNP) | VAF 150/522 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56178347; called by muse, mutect2, varscan2
- PLA2R1 | c.3721T>C p.S1241P | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV51776778; called by muse, mutect2, varscan2
- PSME4 | c.1673T>C p.I558T | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66364241; called by muse, mutect2, varscan2
- RECQL | c.1216+1G>T p.X406_splice | Splice Site (SNP) | VAF 25/99 reads (25%) | catalogued as COSV101388750, COSV69658422; called by muse, mutect2, varscan2
- RPS6KA6 | c.1120G>A p.G374S | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs1288271564, COSV53117997; called by muse, mutect2, varscan2
- SLC6A18 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs760667203, COSV57250372; called by muse, mutect2, varscan2
- SLC9A2 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs144961744; called by muse, mutect2, varscan2
- SPTA1 | c.7176G>T p.M2392I | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63524296; called by muse, mutect2, varscan2
- TJP1 | c.2584C>T p.L862F | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs370774822; called by muse, mutect2, varscan2
- TLN1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.355); catalogued as rs1303627949, COSV59205980; called by muse, mutect2, varscan2
- TMEM45B | c.154A>G p.I52V | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1454616760, COSV55653621; called by muse, mutect2, varscan2
- ADNP | c.1195dup p.A399Gfs*41 | Frame Shift Ins (INS) | VAF 44/183 reads (24%) | called by mutect2, pindel, varscan2
- GIMAP1 | c.301_304del p.R101Vfs*17 | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | called by mutect2, pindel, varscan2
- PTEN | c.387_389delinsCC p.R130Qfs*4 | Frame Shift Del (DEL) | VAF 114/422 reads (27%) | called by pindel, varscan2*
- LRRC37A | c.3939C>T p.H1313= | Silent (SNP) | VAF 74/125 reads (59%) | catalogued as COSV57225464; called by muse, mutect2, varscan2
- MTMR1 | c.888G>A p.P296= | Silent (SNP) | VAF 38/154 reads (25%) | catalogued as rs782426732, COSV64892315; called by muse, mutect2, varscan2
- MUC5B | c.11049C>A p.P3683= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1336252824, COSV71591039; called by muse, mutect2, varscan2
- NFASC | c.933C>T p.S311= (on ENST00000339876 / NM_001378329.1; = p.S322= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs781267185, COSV58362572, COSV58365611; called by muse, mutect2, varscan2
- PCDHA6 | c.1824G>C p.S608= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs782789312, COSV100971175, COSV65343226, COSV65345214; called by muse, mutect2, varscan2
- PLAT | c.966C>T p.H322= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV54274273, COSV99535422; called by muse, mutect2, varscan2
- TTC21A | c.1560C>T p.A520= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV57184080; called by muse, mutect2
- USP25 | c.1701G>A p.Q567= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as COSV53482739; called by muse, mutect2, varscan2
- ZBTB22 | c.1377G>A p.T459= | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as rs749582553, COSV56467988; called by muse, mutect2, varscan2
- ZFP57 | c.1284C>A p.V428= | Silent (SNP) | VAF 76/246 reads (31%) | catalogued as COSV65305875, COSV65306329; called by muse, mutect2, varscan2
